Somatic mutation profile of tumor specimen C3L-06200-02 (aliquot CPT0425860006) from CPTAC case C3L-06200, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 82.5 years (30,121 days).
Specimen C3L-06200-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d57fb1d6-532a-4646-80dd-bf7c30f2d8dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06200-31 (Blood Derived Normal), aliquot CPT0425970003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d440c2cc-218b-4e22-8a56-e4190a92d92a

The open-access MAF lists 857 somatic variants for this specimen: 557 protein-altering or splice-affecting, 264 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 513, Silent 264, Nonsense Mutation 27, Intron 19, Splice Region 7, 3'UTR 7, 5'Flank 4, RNA 4, In Frame Ins 2, 5'UTR 2, Frame Shift Del 2, Translation Start Site 2.

Variants (750 of 857; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 164/325 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 163/325 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 76/259 reads (29%) | catalogued as rs770786127, COSV60692609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 179/284 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PAX6 | c.794G>A p.W265* | Nonsense Mutation (SNP) | VAF 86/347 reads (25%) | catalogued as rs1131692314, CM941145, COSV53795564; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11028T>A p.N3676K | Missense Mutation (SNP) | VAF 110/565 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71294980; called by muse, mutect2, varscan2
- ABCB5 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 80/365 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1176894101; called by muse, mutect2, varscan2
- ABCC12 | c.3211C>T p.Q1071* | Nonsense Mutation (SNP) | VAF 99/311 reads (32%) | catalogued as rs147446673; called by muse, mutect2, varscan2
- ACAD11 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1246082542; called by muse, mutect2, varscan2
- ADAM12 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 185/306 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV64106644; called by muse, mutect2, varscan2
- ADAM18 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV99695354; called by muse, mutect2, varscan2
- ADAMTS16 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 153/592 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV56995099, COSV57011122; called by muse, mutect2, varscan2
- ADH1A | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 107/365 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs201934016; called by muse, mutect2, varscan2
- ADIPOQ | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 168/526 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs773481082; called by muse, mutect2, varscan2
- AGL | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 95/416 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV99648433; called by muse, mutect2, varscan2
- AL121899.2 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 185/545 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs562802461, COSV101198436; called by muse, mutect2, varscan2
- ANGPTL5 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 113/378 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV57531776; called by muse, mutect2, varscan2
- ANK3 | c.12004G>A p.G4002R | Missense Mutation (SNP) | VAF 163/352 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV55058784; called by muse, mutect2, varscan2
- ANKRD18A | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 192/285 reads (67%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.695); catalogued as COSV100511596; called by muse, mutect2, varscan2
- ANKS1B | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 87/315 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs1252788622, COSV59116505; called by muse, mutect2, varscan2
- ANO4 | c.2513G>A p.R838Q (on ENST00000392977 / NM_001286615.2; = p.R803Q on NM_178826.4) | Missense Mutation (SNP) | VAF 134/450 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.202); catalogued as rs778005685, COSV54596564, COSV54598541; called by muse, mutect2, varscan2
- ANP32A | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 84/342 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV51189632; called by muse, varscan2
- APOB | c.2428C>T p.P810S | Missense Mutation (SNP) | VAF 215/365 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as rs934934230; called by muse, mutect2, varscan2
- ARHGEF10 | c.3338C>T p.S1113F (on ENST00000398564; = p.S1088F on NM_014629.4) | Missense Mutation (SNP) | VAF 200/594 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100035455, COSV50646064; called by muse, mutect2, varscan2
- ARHGEF5 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 144/1952 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs749250615, COSV99282455; called by muse, mutect2
- ARHGEF5 | c.3614C>T p.S1205L | Missense Mutation (SNP) | VAF 114/1234 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV50212784; called by muse, mutect2
- BDKRB2 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV60016519; called by muse, mutect2, varscan2
- BEND2 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 151/365 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.101); catalogued as COSV66217614; called by muse, mutect2, varscan2
- BEST3 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 147/499 reads (29%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs748136001, COSV58307113; called by muse, mutect2, varscan2
- BFAR | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 160/598 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs759302751; called by muse, mutect2
- BHMG1 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 170/544 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs555667082; called by muse, varscan2
- BMP7 | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 156/505 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV101215337; called by muse, mutect2, varscan2
- BRWD1 | c.4297C>T p.R1433* | Nonsense Mutation (SNP) | VAF 83/353 reads (24%) | catalogued as rs752494269, COSV60892572; called by muse, mutect2, varscan2
- BTBD8 | c.3778G>A p.D1260N (on ENST00000636805 / NM_001376131.1; = p.D747N on NM_015237.4) | Missense Mutation (SNP) | VAF 109/437 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs920372582, COSV64883560; called by muse, mutect2, varscan2
- C14orf39 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs140979794; called by muse, mutect2, varscan2
- C15orf40 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 128/413 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs756993991; called by muse, mutect2, varscan2
- CACNA1D | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 132/424 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV55438135, COSV55448099; called by muse, mutect2, varscan2
- CATSPER1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 187/586 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as rs201253357; called by muse, mutect2, varscan2
- CBLB | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.007); catalogued as rs1311016924, COSV51425317; called by muse, mutect2, varscan2
- CCDC168 | c.10315G>A p.G3439R | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.145); catalogued as COSV59423764; called by muse, mutect2, varscan2
- CD163L1 | c.2902C>T p.H968Y | Missense Mutation (SNP) | VAF 127/458 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as COSV58024433; called by muse, mutect2, varscan2
- CD209 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 225/687 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1379966036; called by muse, mutect2, varscan2
- CDHR4 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 115/439 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1167078921; called by muse, mutect2, varscan2
- CENPE | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 64/274 reads (23%) | catalogued as COSV54383688; called by muse, mutect2, varscan2
- CFAP54 | c.3998C>T p.P1333L | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs1348659568; called by muse, mutect2, varscan2
- CHAF1A | c.2068T>C p.W690R | Missense Mutation (SNP) | VAF 169/522 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774303475; called by muse, mutect2, varscan2
- CHST12 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 130/684 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99324460; called by muse, mutect2, varscan2
- CNGA2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 166/383 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs764689669, COSV61702940; called by muse, mutect2, varscan2
- CNTN5 | c.2239C>T p.R747* | Nonsense Mutation (SNP) | VAF 124/395 reads (31%) | catalogued as rs780931539, COSV54291267; called by muse, mutect2, varscan2
- COL10A1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 161/352 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV54573660; called by muse, mutect2, varscan2
- COL21A1 | c.2084G>A p.G695E | Missense Mutation (SNP) | VAF 182/271 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769722166, COSV55163893, COSV99778638; called by muse, mutect2, varscan2
- COL26A1 | c.665G>A p.R222Q (on ENST00000313669 / NM_001278563.3; = p.R220Q on NM_133457.4) | Missense Mutation (SNP) | VAF 131/602 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs775714766, COSV58129983; called by muse, mutect2, varscan2
- COL5A3 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 116/396 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.17); catalogued as rs762132898; called by muse, mutect2, varscan2
- CORO1A | c.587G>C p.R196P | Missense Mutation (SNP) | VAF 138/459 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV54630764; called by muse, mutect2, varscan2
- CREB3L2 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 153/659 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57796241; called by muse, mutect2, varscan2
- CRNKL1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as rs1458271018; called by muse, mutect2, varscan2
- CRNN | c.538A>G p.S180G | Missense Mutation (SNP) | VAF 275/458 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55122877; called by muse, mutect2, varscan2
- CSMD2 | c.10091C>T p.S3364F | Missense Mutation (SNP) | VAF 104/356 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.781); catalogued as rs752644843; called by muse, mutect2, varscan2
- CSMD2 | c.3343C>T p.P1115S | Missense Mutation (SNP) | VAF 165/532 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53961572; called by muse, mutect2, varscan2
- CSMD3 | c.10057G>A p.E3353K (on ENST00000297405 / NM_001363185.1; = p.E3184K on NM_052900.3) | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.095); catalogued as COSV52358313; called by muse, mutect2, varscan2
- CTC1 | c.610C>T p.L204F | Missense Mutation (SNP) | VAF 122/397 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.069); catalogued as COSV59851982; called by muse, mutect2, varscan2
- CYBB | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 103/244 reads (42%) | catalogued as COSV66086683; called by muse, mutect2, varscan2
- CYLC1 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as rs866438736; called by muse, mutect2, varscan2
- CYP2C9 | c.1329G>A p.M443I | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV99583348; called by muse, mutect2, varscan2
- DAPK1 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 128/236 reads (54%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.698); catalogued as rs930286884, COSV63785157; called by muse, mutect2
- DBX2 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 170/546 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs766187055; called by muse, mutect2, varscan2
- DCC | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 83/500 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV59132001; called by muse, mutect2, varscan2
- DCC | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 77/266 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs181040857; called by muse, mutect2, varscan2
- DCC | c.2197C>T p.H733Y | Missense Mutation (SNP) | VAF 90/503 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59085186; called by muse, mutect2, varscan2
- DLG2 | c.2492G>A p.G831E | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1440742541; called by muse, mutect2, varscan2
- DLGAP3 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 201/601 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.541); catalogued as COSV52395202; called by muse, mutect2, varscan2
- DMBT1 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 103/243 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV57537731; called by muse, mutect2, varscan2
- DMXL2 | c.1290T>G p.D430E | Missense Mutation (SNP) | VAF 80/281 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs775660410; called by muse, mutect2, varscan2
- DNAH3 | c.5359C>T p.R1787C | Missense Mutation (SNP) | VAF 110/344 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146173789; called by muse, mutect2, varscan2
- DNAH5 | c.12735G>A p.M4245I | Missense Mutation (SNP) | VAF 200/434 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54201432; called by muse, mutect2, varscan2
- DST | c.8645C>T p.P2882L | Missense Mutation (SNP) | VAF 130/310 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.039); catalogued as rs551585499; called by muse, mutect2, varscan2
- ELOVL4 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 145/328 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1207102482; called by muse, mutect2, varscan2
- EMILIN2 | c.1436T>A p.I479N | Missense Mutation (SNP) | VAF 125/590 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV54427224; called by muse, mutect2, varscan2
- ERBB4 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 197/344 reads (57%) | catalogued as COSV53574312; called by muse, mutect2, varscan2
- ERVV-2 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 142/496 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.508); catalogued as COSV74153549; called by muse, mutect2, varscan2
- FAM110B | c.726C>A p.D242E | Missense Mutation (SNP) | VAF 174/562 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770472744; called by muse, mutect2, varscan2
- FAM124B | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 326/519 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs371374350; called by muse, mutect2, varscan2
- FAM133A | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 145/336 reads (43%) | catalogued as COSV59073947; called by muse, mutect2, varscan2
- FAM214A | c.2392C>T p.H798Y | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as COSV55924293; called by muse, mutect2, varscan2
- FAM83A | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52686313; called by muse, mutect2, varscan2
- FAT4 | c.4735C>T p.R1579C | Missense Mutation (SNP) | VAF 150/469 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs372570229; called by muse, mutect2, varscan2
- FEM1A | c.1528T>C p.C510R | Missense Mutation (SNP) | VAF 149/478 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.788); catalogued as rs771857085; called by muse, mutect2, varscan2
- FLG | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 137/233 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV64237841, COSV64239483; called by muse, mutect2, varscan2
- FREM2 | c.3748G>A p.E1250K | Missense Mutation (SNP) | VAF 132/406 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1000912828, COSV54829636; called by muse, varscan2
- FRMD4B | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 100/331 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.112); catalogued as rs1206138312, COSV68334218; called by muse, mutect2, varscan2
- FSTL5 | c.2513G>A p.G838E | Missense Mutation (SNP) | VAF 107/315 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60188547; called by muse, mutect2, varscan2
- FUT9 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs866379874, COSV56144259; called by muse, mutect2, varscan2
- GABRQ | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 174/369 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs782766146, COSV64780696; called by muse, mutect2, varscan2
- GATA2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 183/537 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs1430054108; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs144857905; called by muse, mutect2, varscan2
- GFPT2 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 194/350 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs753407984; called by muse, mutect2, varscan2
- GLI1 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 154/462 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV57365333; called by muse, mutect2, varscan2
- GLRA2 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54341318; called by muse, mutect2, varscan2
- GOLGA5 | c.524C>A p.S175Y | Missense Mutation (SNP) | VAF 83/363 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV99370832; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 150/952 reads (16%) | SIFT deleterious, low confidence (0.01); catalogued as rs1461586281, COSV61477092; called by muse, mutect2
- GPR39 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 280/437 reads (64%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs1558870525; called by muse, mutect2, varscan2
- GRIA1 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 252/419 reads (60%) | catalogued as COSV53625087; called by muse, mutect2, varscan2
- GRIN2B | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 130/479 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74207423; called by muse, mutect2, varscan2
- GRM3 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 276/556 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64468191; called by muse, mutect2, varscan2
- HEPHL1 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as COSV100244619; called by muse, varscan2
- HNF1B | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 215/602 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs748416956; called by muse, mutect2, varscan2
- HS3ST4 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 139/473 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs867965756, COSV58804388; called by muse, mutect2, varscan2
- IFT43 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 86/335 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV53138238; called by muse, mutect2, varscan2
- IGF2 | c.685C>T p.P229S (on ENST00000434045 / NM_001127598.3; = p.P173S on NM_000612.6) | Missense Mutation (SNP) | VAF 148/465 reads (32%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs11545014; called by muse, mutect2, varscan2
- IGHV1-46 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 110/386 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as rs372749973; called by muse, mutect2, varscan2
- IQCN | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 156/591 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.249); catalogued as rs1182788702; called by muse, mutect2, varscan2
- ITGA8 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 137/332 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV100959907; called by muse, mutect2, varscan2
- ITIH2 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV100623401; called by muse, mutect2, varscan2
- KHDRBS2 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 180/392 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as rs865838310; called by muse, mutect2, varscan2
- KMT2D | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 176/583 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV56409379; called by muse, mutect2, varscan2
- KPTN | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs1285953082; called by muse, mutect2, varscan2
- KRBA1 | c.2468G>A p.G823D | Missense Mutation (SNP) | VAF 328/1097 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330507517; called by muse, mutect2, varscan2
- KRT12 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 111/402 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as rs146332400; called by muse, mutect2, varscan2
- KRT23 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 124/444 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); catalogued as COSV52927550; called by muse, mutect2, varscan2
- KRT25 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 112/393 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.314); catalogued as rs773734449; called by muse, mutect2, varscan2
- KRT5 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 176/561 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs11549952; called by muse, mutect2, varscan2
- KRT6A | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 76/423 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as rs1187060006; called by muse, mutect2, varscan2
- KRTAP12-2 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 206/617 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100554495; called by muse, mutect2, varscan2
- LAIR2 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs147517598; called by mutect2, varscan2
- LAMA1 | c.3925G>A p.D1309N | Missense Mutation (SNP) | VAF 173/375 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67542952, COSV67545699; called by muse, mutect2, varscan2
- LCORL | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 91/330 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.026); catalogued as rs1246252373; called by muse, mutect2, varscan2
- LPAR1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 220/349 reads (63%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV62688892; called by muse, mutect2, varscan2
- LPL | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 127/439 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60931532; called by muse, mutect2, varscan2
- LRP1B | c.8104G>A p.D2702N | Missense Mutation (SNP) | VAF 147/258 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs772783794, COSV67257857; called by muse, mutect2, varscan2
- LRRC72 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 235/533 reads (44%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1465442914, COSV101181330; called by muse, mutect2, varscan2
- LRRIQ3 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV63041391; called by muse, mutect2, varscan2
- MAGEA6 | c.914A>T p.H305L | Missense Mutation (SNP) | VAF 104/239 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV61449391; called by muse, mutect2, varscan2
- MAGEC1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 184/368 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1469473688, COSV53567904; called by muse, mutect2, varscan2
- MAGEC1 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 190/459 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.058); catalogued as COSV99594673; called by muse, mutect2, varscan2
- MAGEC3 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 109/234 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV68924358; called by muse, mutect2, varscan2
- MALRD1 | c.2885G>A p.R962Q | Missense Mutation (SNP) | VAF 127/265 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs140205728; called by muse, mutect2, varscan2
- MAN2C1 | c.2162C>T p.A721V | Missense Mutation (SNP) | VAF 132/392 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs150336317; called by muse, mutect2, varscan2
- MAP2 | c.5425C>T p.P1809S | Missense Mutation (SNP) | VAF 307/471 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762018785; called by muse, mutect2, varscan2
- MATN4 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 134/468 reads (29%) | PolyPhen probably damaging (0.999); catalogued as rs939059210, COSV59213375; called by muse, varscan2
- ME1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553218395; called by muse, varscan2
- MECOM | c.2743G>A p.E915K (on ENST00000468789 / NM_001105078.4; = p.E1103K on NM_004991.4) | Missense Mutation (SNP) | VAF 83/321 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV52977561; called by muse, mutect2, varscan2
- MGAM2 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 113/556 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.093); catalogued as rs1469143931; called by muse, mutect2, varscan2
- MLIP | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 81/360 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs761764090, COSV99228941; called by muse, mutect2, varscan2
- MLKL | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 77/271 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV58206192; called by muse, mutect2, varscan2
- MLXIPL | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 350/772 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.112); catalogued as COSV57666915; called by muse, mutect2, varscan2
- MMP16 | c.304G>C p.G102R | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54149241; called by muse, mutect2, varscan2
- MMRN1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 79/280 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV53335491; called by muse, mutect2, varscan2
- MRAP2 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 101/218 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.297); catalogued as rs147564754, COSV57633642; called by muse, mutect2, varscan2
- MRTFA | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 92/354 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62931221; called by muse, mutect2, varscan2
- MTOR | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 125/402 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63869057; called by muse, mutect2, varscan2
- MUC16 | c.38605G>A p.E12869K | Missense Mutation (SNP) | VAF 92/330 reads (28%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.365); catalogued as rs1196350883, COSV67484969; called by muse, mutect2, varscan2
- MUC16 | c.26365C>T p.P8789S | Missense Mutation (SNP) | VAF 96/428 reads (22%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.007); catalogued as COSV101200678; called by muse, mutect2, varscan2
- MUC16 | c.1736G>A p.G579E | Missense Mutation (SNP) | VAF 134/443 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); catalogued as rs758480970, COSV67482830; called by muse, mutect2, varscan2
- MUC5B | c.7292G>A p.G2431E | Missense Mutation (SNP) | VAF 177/600 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1386648655; called by muse, mutect2, varscan2
- MYH1 | c.3863C>T p.S1288L | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99875976; called by muse, varscan2
- MYH1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs534756197; called by muse, mutect2, varscan2
- MYH15 | c.2854G>A p.G952R | Missense Mutation (SNP) | VAF 110/410 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV56319678; called by muse, mutect2, varscan2
- MYO16 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 93/265 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs1306709001; called by muse, mutect2, varscan2
- MYO16 | c.3256G>A p.D1086N | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.53); catalogued as COSV62750452; called by muse, mutect2, varscan2
- NCKAP5 | c.2785C>T p.P929S | Missense Mutation (SNP) | VAF 281/459 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs371602418; called by muse, mutect2, varscan2
- NCR3LG1 | c.1340C>A p.P447Q | Missense Mutation (SNP) | VAF 80/295 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV59069574; called by muse, mutect2, varscan2
- NISCH | c.3635C>T p.T1212I | Missense Mutation (SNP) | VAF 94/407 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV58732413; called by muse, mutect2, varscan2
- NOVA1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 137/438 reads (31%) | catalogued as COSV57472701, COSV57490260; called by muse, mutect2, varscan2
- NTM | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs865924953, COSV66179519; called by muse, mutect2, varscan2
- OAZ1 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 148/450 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as rs1370574319; called by muse, mutect2, varscan2
- OBP2B | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 233/421 reads (55%) | SIFT tolerated (0.66); PolyPhen benign (0.037); catalogued as COSV64402243; called by muse, mutect2, varscan2
- OPRK1 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 92/340 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55569122; called by muse, mutect2, varscan2
- OR11H7 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 125/391 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778110871; called by muse, mutect2, varscan2
- OR1Q1 | c.822A>G p.I274M | Missense Mutation (SNP) | VAF 276/459 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs376547924; called by muse, mutect2, varscan2
- OR2F2 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 115/753 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs199756492; called by muse, mutect2, varscan2
- OR4C13 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 118/418 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs563481475; called by muse, mutect2, varscan2
- OR4K1 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 80/287 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs868103485, COSV53462356; called by muse, mutect2, varscan2
- OR4K5 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60002438; called by muse, mutect2, varscan2
- OR51L1 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 115/348 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748049886; called by muse, mutect2, varscan2
- OR52I2 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 166/516 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.345); catalogued as rs1314208330, COSV57045063; called by muse, mutect2, varscan2
- OR56A4 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 110/415 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs867126571; called by muse, mutect2, varscan2
- OR5B2 | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 118/392 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV56909729; called by muse, mutect2, varscan2
- OR5D18 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV61736761; called by muse, mutect2, varscan2
- OR5H14 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 94/428 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765393898, COSV71194285; called by muse, varscan2
- OR5W2 | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 112/368 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs868531624, COSV60615735; called by muse, mutect2, varscan2
- OTOL1 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 127/417 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs866413661; called by muse, mutect2, varscan2
- P3H3 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 146/421 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs781811454, COSV99300915; called by muse, mutect2, varscan2
- PABPC1L | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 133/423 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1428982021; called by muse, mutect2, varscan2
- PAK5 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 129/419 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV62037415; called by muse, mutect2, varscan2
- PCDHB7 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 229/360 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV50754458, COSV50769361; called by muse, mutect2, varscan2
- PCLO | c.11198C>T p.S3733F | Missense Mutation (SNP) | VAF 114/568 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV61622891, COSV61668169; called by muse, mutect2, varscan2
- PDE3A | c.2911G>A p.E971K | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62967633, COSV62978321; called by muse, mutect2, varscan2
- PDE3B | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 154/564 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.514); catalogued as rs551366523; called by muse, mutect2, varscan2
- PDGFRA | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.034); catalogued as COSV57272921; called by muse, mutect2, varscan2
- PIK3C2G | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 94/289 reads (33%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.591); catalogued as COSV56824663; called by muse, mutect2, varscan2
- PLA2R1 | c.4369G>A p.D1457N | Missense Mutation (SNP) | VAF 81/164 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs760757680; called by muse, mutect2, varscan2
- PLCB4 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 132/438 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53803703; called by muse, mutect2, varscan2
- PLCB4 | c.2982G>A p.M994I | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs753931051, COSV53798516; called by muse, mutect2, varscan2
- PLG | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 79/153 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99805112; called by muse, mutect2, varscan2
- PLSCR4 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 88/354 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs777508138, COSV100724354, COSV61608458; called by muse, mutect2, varscan2
- PLXDC2 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 99/253 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65906156; called by muse, mutect2, varscan2
- PLXNA4 | c.4872G>A p.M1624I | Missense Mutation (SNP) | VAF 142/326 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.309); catalogued as COSV58134119; called by muse, mutect2, varscan2
- PNPLA3 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 139/449 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs781391159; called by muse, varscan2
- PPFIA2 | c.2695G>A p.D899N | Missense Mutation (SNP) | VAF 79/341 reads (23%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.978); catalogued as COSV61024144; called by muse, mutect2, varscan2
- PRAMEF2 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 144/477 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as rs1324082940, COSV99535244; called by muse, mutect2, varscan2
- PRR36 | c.2944C>T p.L982F | Missense Mutation (SNP) | VAF 126/367 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1230991313; called by muse, mutect2, varscan2
- PRSS1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 91/445 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV61191980; called by muse, mutect2, varscan2
- PTGER3 | c.1081G>A p.E361K (on ENST00000628037 / NM_198717.2; = p.E370K on NM_198716.2) | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs771757558, COSV63388000; called by muse, mutect2, varscan2
- PTPRT | c.3925G>A p.D1309N | Missense Mutation (SNP) | VAF 102/371 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs765339833, COSV62013834, COSV62021981; called by muse, mutect2, varscan2
- PTPRZ1 | c.3686C>T p.S1229F | Missense Mutation (SNP) | VAF 238/516 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV66447862; called by muse, mutect2, varscan2
- RAB25 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 182/274 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs749179888; called by muse, mutect2, varscan2
- RALYL | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 95/361 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs376378537; called by muse, mutect2, varscan2
- RAX | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 186/777 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs1368829275; called by muse, mutect2, varscan2
- RBM15B | c.1922C>T p.S641F | Missense Mutation (SNP) | VAF 164/540 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.157); catalogued as rs782108410, COSV60045871; called by muse, mutect2, varscan2
- RBM47 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 161/582 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV55944551; called by muse, mutect2, varscan2
- REXO1 | c.2954C>T p.S985L | Missense Mutation (SNP) | VAF 145/499 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV99402710; called by muse, mutect2, varscan2
- RFPL2 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.166); catalogued as rs1264351599, COSV50719502; called by muse, mutect2
- RFX6 | c.2702C>T p.S901F | Missense Mutation (SNP) | VAF 122/294 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as rs750442479, COSV100263571; called by muse, mutect2, varscan2
- RNLS | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 85/200 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs1028614230; called by muse, mutect2, varscan2
- ROS1 | c.2401C>T p.L801F | Missense Mutation (SNP) | VAF 153/354 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1040006908; called by muse, mutect2, varscan2
- RPRD2 | c.3722C>T p.S1241L | Missense Mutation (SNP) | VAF 330/520 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs201836593; called by muse, mutect2, varscan2
- RTL1 | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 161/481 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs188763368; called by muse, mutect2, varscan2
- RTL9 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 170/387 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1372351467; called by muse, mutect2, varscan2
- RYR1 | c.6070C>T p.P2024S | Missense Mutation (SNP) | VAF 106/364 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.242); catalogued as rs779178878; called by muse, mutect2, varscan2
- RYR2 | c.12857C>T p.S4286F | Missense Mutation (SNP) | VAF 85/255 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63692249; called by muse, mutect2, varscan2
- SALL3 | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 190/894 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.118); catalogued as COSV73305823; called by muse, mutect2, varscan2
- SBF2 | c.3466C>T p.L1156F | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as rs1433995523, COSV56297642; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SBK2 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 191/636 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs942437153; called by muse, mutect2, varscan2
- SCN5A | c.3169G>A p.D1057N | Missense Mutation (SNP) | VAF 171/539 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as rs1432833848; called by muse, mutect2, varscan2
- SCN5A | c.1736G>A p.G579E | Missense Mutation (SNP) | VAF 180/591 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.321); catalogued as rs867634347, COSV61140520; called by muse, mutect2, varscan2
- SEL1L2 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 95/341 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469242996; called by muse, mutect2, varscan2
- SEMA3E | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 106/220 reads (48%) | catalogued as rs965528935, COSV57082291; called by muse, mutect2, varscan2
- SEMG2 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 130/409 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV101034103, COSV65647725; called by muse, mutect2, varscan2
- SERPINA11 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 111/351 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1366468410, COSV58243595; called by muse, mutect2, varscan2
- SERPINA4 | c.924G>A p.R308= | Splice Region (SNP) | VAF 64/215 reads (30%) | catalogued as rs1278001819, COSV54069477; called by muse, mutect2, varscan2
- SERPINB7 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 59/298 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.018); catalogued as COSV60532670; called by muse, mutect2, varscan2
- SH3PXD2B | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 212/351 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as COSV61124469; called by muse, mutect2, varscan2
- SH3RF2 | c.941C>A p.S314Y | Missense Mutation (SNP) | VAF 318/482 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63037463, COSV63038515; called by muse, mutect2, varscan2
- SI | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100013882, COSV100014430, COSV52265616; called by muse, mutect2, varscan2
- SIGLEC7 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 125/461 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as rs777489435, COSV58317427; called by muse, mutect2, varscan2
- SLC17A6 | c.1081A>T p.I361F | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV54142566; called by muse, mutect2, varscan2
- SLC27A2 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 79/306 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755222778, COSV51058622; called by muse, mutect2, varscan2
- SLC4A4 | c.1276G>A p.G426R (on ENST00000264485 / NM_001098484.3; = p.G382R on NM_003759.4) | Missense Mutation (SNP) | VAF 119/420 reads (28%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.806); catalogued as rs760529597, COSV52625372; called by muse, mutect2, varscan2
- SLC4A9 | c.1192C>T p.P398S (on ENST00000507527 / NM_001258428.2; = p.P374S on NM_031467.3) | Missense Mutation (SNP) | VAF 242/392 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1313247709; called by muse, mutect2, varscan2
- SLC9C1 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV59885674; called by muse, mutect2, varscan2
- SPACA7 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 121/405 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs1244291109, COSV52098307; called by muse, mutect2, varscan2
- SPATA31D1 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 100/179 reads (56%) | catalogued as COSV61202159; called by muse, mutect2, varscan2
- SPATA31D3 | c.2612G>A p.R871Q | Missense Mutation (SNP) | VAF 336/948 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs763286928, COSV61986432; called by muse, mutect2, varscan2
- SPEF2 | c.5380G>A p.D1794N | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.898); catalogued as COSV57428426; called by muse, mutect2, varscan2
- SPOCK1 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 230/382 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs267600350, COSV56458405; called by muse, mutect2, varscan2
- SRRM4 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 166/511 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.033); catalogued as COSV57419476; called by muse, mutect2, varscan2
- ST8SIA3 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 124/562 reads (22%) | PolyPhen probably damaging (0.999); catalogued as COSV60655645; called by muse, mutect2, varscan2
- STOX2 | c.1844C>T p.S615L | Missense Mutation (SNP) | VAF 164/481 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs368929688; called by muse, mutect2, varscan2
- STYXL1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 81/472 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs782034758; called by muse, mutect2, varscan2
- SUSD2 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 143/438 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as rs763053320, COSV64203596; called by muse, mutect2, varscan2
- SVEP1 | c.7247G>A p.G2416E | Missense Mutation (SNP) | VAF 94/352 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV52839313; called by muse, mutect2, varscan2
- SVOPL | c.1298G>A p.G433E (on ENST00000419765; = p.G281E on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 252/556 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185851913, COSV55993195; called by muse, mutect2, varscan2
- TAS2R16 | c.77G>A p.S26N | Missense Mutation (SNP) | VAF 108/537 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as rs371492472; called by muse, mutect2, varscan2
- TCTN2 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 87/368 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV57635322; called by muse, mutect2, varscan2
- TDRD15 | c.4375G>A p.E1459K | Missense Mutation (SNP) | VAF 99/154 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1195755199; called by muse, mutect2, varscan2
- TENM2 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 132/229 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.993); catalogued as rs373360913, COSV69133439; called by muse, mutect2, varscan2
- TENM3 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 150/475 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as rs771498932, COSV101305515; called by muse, mutect2, varscan2
- TERT | c.2471C>T p.S824F | Missense Mutation (SNP) | VAF 80/393 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV57211430; called by muse, mutect2, varscan2
- TJAP1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 367/515 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs563916607; called by muse, mutect2, varscan2
- TLR4 | c.1615C>T p.P539S (on ENST00000355622 / NM_138554.5; = p.P499S on NM_003266.4) | Missense Mutation (SNP) | VAF 234/395 reads (59%) | SIFT tolerated (0.45); PolyPhen benign (0.033); catalogued as COSV62924105; called by muse, mutect2, varscan2
- TMEM151A | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 156/561 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs1432580903; called by muse, mutect2, varscan2
- TMPRSS9 | c.581C>T p.S194F (on ENST00000648592; = p.S160F on NM_182973.2) | Missense Mutation (SNP) | VAF 82/279 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs770258343, COSV60227090; called by muse, mutect2, varscan2
- TRBV5-1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 130/235 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs757106114; called by muse, mutect2, varscan2
- TRIML1 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 101/393 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs1316000776, COSV60194018, COSV60196036; called by muse, mutect2, varscan2
- TRPM2 | c.3778G>A p.E1260K | Missense Mutation (SNP) | VAF 92/353 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV55970134; called by muse, mutect2, varscan2
- TRPM6 | c.5315G>A p.R1772Q | Missense Mutation (SNP) | VAF 325/497 reads (65%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs138982418, COSV62504972; called by muse, mutect2, varscan2
- TSPAN8 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 75/304 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.101); catalogued as COSV56079106; called by muse, mutect2, varscan2
- TTLL9 | c.1242C>T p.L414= | Splice Region (SNP) | VAF 96/260 reads (37%) | catalogued as rs754986295, COSV60589755; called by muse, mutect2, varscan2
- TTN | c.64484G>A p.R21495K (on ENST00000591111; = p.R14071K on NM_003319.4) | Missense Mutation (SNP) | VAF 157/245 reads (64%) | PolyPhen benign (0.003); catalogued as COSV100623395; called by muse, mutect2, varscan2
- TTN | c.44761G>A p.D14921N (on ENST00000591111; = p.D7497N on NM_003319.4) | Missense Mutation (SNP) | VAF 201/340 reads (59%) | PolyPhen probably damaging (0.998); catalogued as COSV59882295; called by muse, mutect2, varscan2
- TUBA3C | c.1177C>T p.H393Y | Missense Mutation (SNP) | VAF 183/613 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV68029202; called by muse, mutect2, varscan2
- TYW1 | c.1408C>A p.R470S | Missense Mutation (SNP) | VAF 62/407 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62755636; called by muse, mutect2, varscan2
- ULK2 | c.2972G>A p.R991H | Missense Mutation (SNP) | VAF 116/400 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1306192989; called by muse, mutect2, varscan2
- VWF | c.8311T>G p.C2771G | Missense Mutation (SNP) | VAF 170/477 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM013056, CM147812; called by muse, mutect2, varscan2
- WNT7A | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 149/450 reads (33%) | catalogued as COSV53201109; called by muse, mutect2, varscan2
- XAB2 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 135/452 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100601438; called by muse, mutect2, varscan2
- ZHX2 | c.2110G>A p.G704S | Missense Mutation (SNP) | VAF 160/486 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs530222617; called by muse, varscan2
- ZNF208 | c.2479C>T p.H827Y | Missense Mutation (SNP) | VAF 100/347 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV68104736; called by muse, mutect2, varscan2
- ZNF547 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 153/523 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as rs149294579; called by muse, mutect2, varscan2
- ZNF598 | c.2144C>T p.S715F | Missense Mutation (SNP) | VAF 79/255 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1279623939; called by muse, mutect2, varscan2
- ZNF682 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 144/508 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1449713177; called by muse, mutect2, varscan2
- ZNF705G | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 148/1271 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.598); catalogued as rs548952183, COSV67951115; called by muse, mutect2, varscan2
- ZNF831 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 131/511 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs756739382, COSV64037250; called by muse, mutect2, varscan2
- ZSWIM2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 144/229 reads (63%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs780115062, COSV54573844; called by muse, mutect2, varscan2
- ZSWIM4 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 146/506 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1445910098; called by muse, mutect2, varscan2
- ABRAXAS1 | c.604T>G p.F202V | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ACAN | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 150/438 reads (34%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- ACSS3 | c.859_868delinsG p.P287_S290delinsA | In Frame Del (DEL) | VAF 95/338 reads (28%) | called by pindel, varscan2*
- ADAMTS19 | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 100/149 reads (67%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADAMTS6 | c.2918C>A p.P973Q | Missense Mutation (SNP) | VAF 149/345 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRE3 | c.1862C>T p.S621F | Missense Mutation (SNP) | VAF 98/371 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ADGRV1 | c.7552G>A p.E2518K | Missense Mutation (SNP) | VAF 292/470 reads (62%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ADNP | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 96/349 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- AKR1C2 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 110/248 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- AKR1D1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 113/562 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- ALAD | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 431/589 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMPD1 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 114/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ANHX | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 134/389 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ANKRD31 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 114/214 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- ANKRD33B | c.763T>C p.F255L | Missense Mutation (SNP) | VAF 349/687 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- AP001781.2 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 76/271 reads (28%) | called by muse, mutect2, varscan2
- AP2A1 | c.1631C>T p.T544I | Missense Mutation (SNP) | VAF 108/424 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- APOB | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 212/364 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- AQP11 | c.233C>A p.T78K | Missense Mutation (SNP) | VAF 152/492 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ARHGAP6 | c.2473C>T p.Q825* (on ENST00000337414 / NM_013427.3; = p.Q622* on NM_013423.3) | Nonsense Mutation (SNP) | VAF 210/505 reads (42%) | called by muse, mutect2, varscan2
- ASNS | c.148T>A p.L50M | Missense Mutation (SNP) | VAF 163/402 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ASTN1 | c.2551C>T p.Q851* | Nonsense Mutation (SNP) | VAF 231/397 reads (58%) | called by muse, mutect2, varscan2
- ASXL3 | c.1264C>A p.L422I | Missense Mutation (SNP) | VAF 109/587 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASXL3 | c.3419C>T p.P1140L | Missense Mutation (SNP) | VAF 243/520 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATAD2B | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 181/292 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ATP2B4 | c.3149C>T p.P1050L | Missense Mutation (SNP) | VAF 223/348 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATRIP | c.712T>C p.C238R | Missense Mutation (SNP) | VAF 90/283 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- AWAT1 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 146/364 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAZ2B | c.3346C>T p.P1116S | Missense Mutation (SNP) | VAF 294/487 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- BBX | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BCL3 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 162/533 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEST3 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- BFAR | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 161/604 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- BIN2 | c.1273A>G p.S425G | Missense Mutation (SNP) | VAF 145/479 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- BOD1L1 | c.1789T>C p.S597P | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- BRINP3 | c.1052T>A p.F351Y | Missense Mutation (SNP) | VAF 208/344 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- BTBD8 | c.2033G>A p.G678E (on ENST00000636805 / NM_001376131.1; = p.G165E on NM_015237.4) | Missense Mutation (SNP) | VAF 156/480 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- C10orf71 | c.3992C>T p.P1331L | Missense Mutation (SNP) | VAF 158/448 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C1orf112 | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- C3 | c.4366G>A p.D1456N | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CA12 | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 83/338 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CADPS2 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 156/360 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CATSPERB | c.1495C>T p.H499Y | Missense Mutation (SNP) | VAF 147/538 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CCDC168 | c.4712G>A p.G1571D | Missense Mutation (SNP) | VAF 151/454 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCR4 | c.47A>C p.Y16S | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCT8L2 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 148/458 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CD163 | c.1333A>G p.N445D | Missense Mutation (SNP) | VAF 136/432 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CEP120 | c.2792G>C p.G931A | Missense Mutation (SNP) | VAF 278/487 reads (57%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP54 | c.3997C>T p.P1333S | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHD9 | c.3700G>A p.G1234R | Missense Mutation (SNP) | VAF 128/354 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHGB | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 152/533 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- CLDN1 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 115/371 reads (31%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- CLIC6 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 190/602 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CMYA5 | c.4185A>T p.E1395D | Missense Mutation (SNP) | VAF 261/424 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- CNGA1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 73/308 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, varscan2
- CNTN6 | c.1173del p.K391Nfs*4 | Frame Shift Del (DEL) | VAF 71/276 reads (26%) | called by mutect2, pindel, varscan2
- COL21A1 | c.1295A>T p.N432I | Missense Mutation (SNP) | VAF 104/382 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- COL9A3 | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 125/472 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CPNE2 | c.50T>G p.M17R | Missense Mutation (SNP) | VAF 147/439 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CR1 | c.4249C>T p.P1417S | Missense Mutation (SNP) | VAF 133/287 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRACDL | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 181/272 reads (67%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CREB5 | c.595G>A p.E199K (on ENST00000357727 / NM_182898.4; = p.E192K on NM_004904.3) | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CSMD3 | c.10184C>A p.P3395H (on ENST00000297405 / NM_001363185.1; = p.P3226H on NM_052900.3) | Missense Mutation (SNP) | VAF 110/354 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CSMD3 | c.5146G>A p.D1716N (on ENST00000297405 / NM_001363185.1; = p.D1612N on NM_052900.3) | Missense Mutation (SNP) | VAF 104/360 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CSNKA2IP | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- CYP1A2 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 91/316 reads (29%) | called by muse, mutect2, varscan2
- CYP4A22 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 138/472 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYP4F8 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 122/426 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DAB2 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 132/514 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DBH | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 245/434 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- DDX54 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 105/403 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLAT | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DMD | c.3586G>A p.A1196T | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DMRTB1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 167/558 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- DNAH5 | c.3245G>A p.G1082E | Missense Mutation (SNP) | VAF 137/309 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH9 | c.10604T>A p.F3535Y | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNAH9 | c.12187G>A p.E4063K | Missense Mutation (SNP) | VAF 140/569 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DPYD | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 100/365 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DSCAM | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 123/408 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- DSCAML1 | c.5354G>A p.G1785E (on ENST00000321322; = p.G1725E on NM_020693.4) | Missense Mutation (SNP) | VAF 72/304 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFR3A | c.1679T>A p.I560N | Missense Mutation (SNP) | VAF 86/332 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- EPHA4 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 147/235 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERCC8 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 57/322 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- EVPL | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 168/610 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- EXOC3L2 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 163/541 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EXT1 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- FAM184A | c.1262G>A p.R421K | Missense Mutation (SNP) | VAF 130/281 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAM186A | c.1203G>A p.W401* | Nonsense Mutation (SNP) | VAF 131/406 reads (32%) | called by muse, mutect2, varscan2
- FAT4 | c.8006C>T p.P2669L | Missense Mutation (SNP) | VAF 103/384 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCN2 | c.433T>A p.F145I | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FGG | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 149/484 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- FLNC | c.5276C>T p.P1759L | Missense Mutation (SNP) | VAF 104/599 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXJ3 | c.1684_1701dup p.S562_P567dup | In Frame Ins (INS) | VAF 52/242 reads (21%) | called by mutect2, varscan2
- FRMPD2 | c.1906G>A p.G636R | Missense Mutation (SNP) | VAF 105/252 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- GALNT6 | c.590T>G p.V197G | Missense Mutation (SNP) | VAF 149/517 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GASK1B | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 165/565 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GEN1 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 141/238 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- GOLGA6L2 | c.2198G>A p.G733E | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- GOLGA6L22 | c.641A>T p.Q214L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GPATCH8 | c.564dup p.Q189Tfs*10 | Frame Shift Ins (INS) | VAF 108/396 reads (27%) | called by mutect2, pindel, varscan2
- GPR176 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 139/333 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- GPR179 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 150/510 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- GPR19 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 91/379 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- GRIA3 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 98/215 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIK2 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 115/245 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- GRIN2B | c.1201C>A p.Q401K | Missense Mutation (SNP) | VAF 100/314 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0); called by mutect2, varscan2
- HDAC10 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 161/560 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- HEATR5A | c.4714T>A p.S1572T | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- HECTD4 | c.12806C>T p.P4269L | Missense Mutation (SNP) | VAF 118/435 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- HFM1 | c.1683G>A p.Q561= | Splice Region (SNP) | VAF 49/181 reads (27%) | called by muse, mutect2, varscan2
- HNMT | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 120/209 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HTRA1 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- HUNK | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ID2 | c.67_68del p.S23Pfs*96 | Frame Shift Del (DEL) | VAF 202/416 reads (49%) | called by pindel, varscan2
- IFNA8 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 202/338 reads (60%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- IGHG2 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 182/1595 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL21 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 103/382 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INTS2 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 106/370 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- IQCN | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 156/594 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- IREB2 | c.2260C>T p.H754Y | Missense Mutation (SNP) | VAF 137/484 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IRX2 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 234/540 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRX2 | c.364A>T p.T122S | Missense Mutation (SNP) | VAF 231/534 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ITGAM | c.309G>A p.L103= | Splice Region (SNP) | VAF 99/365 reads (27%) | called by muse, mutect2, varscan2
- ITSN1 | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 129/426 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KCNB2 | c.1697G>A p.R566K | Missense Mutation (SNP) | VAF 130/450 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNQ5 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 220/470 reads (47%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM4E | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 173/593 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1109 | c.12818G>A p.R4273K | Missense Mutation (SNP) | VAF 93/327 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- KIF21A | c.3262A>G p.K1088E (on ENST00000361418 / NM_001378440.1; = p.K1075E on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/350 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.857); called by muse, varscan2
- KIF5C | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 197/313 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- KLHL4 | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 120/290 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KPNA4 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- KRT20 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 145/536 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- KRT33B | c.740T>C p.F247S | Missense Mutation (SNP) | VAF 141/428 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- KRTAP10-8 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 162/598 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LAMA1 | c.8552G>A p.G2851E | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LAMA2 | c.4726G>A p.D1576N | Missense Mutation (SNP) | VAF 105/198 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA5 | c.8051C>T p.S2684F | Missense Mutation (SNP) | VAF 104/346 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LIMCH1 | c.3145C>T p.L1049F | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRCH4 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 155/643 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- LRTM1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 131/421 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- MALRD1 | c.5926G>A p.E1976K | Missense Mutation (SNP) | VAF 93/185 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MMP27 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 105/328 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MSLN | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 175/566 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- MTA1 | c.366C>T p.I122= | Splice Region (SNP) | VAF 94/333 reads (28%) | called by muse, mutect2, varscan2
- MUC16 | c.39442G>A p.G13148R | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC16 | c.25922C>T p.P8641L | Missense Mutation (SNP) | VAF 166/553 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- MUC16 | c.9314G>A p.G3105E | Missense Mutation (SNP) | VAF 147/491 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MYH11 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 112/407 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- MYH4 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 133/456 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- MYO18B | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 135/441 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO19 | c.2152C>A p.L718I (on ENST00000614623 / NM_001163735.1; = p.L518I on NM_025109.5) | Missense Mutation (SNP) | VAF 178/620 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NAPA | c.174G>T p.W58C | Missense Mutation (SNP) | VAF 84/351 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCKAP1L | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 127/401 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NEK10 | c.3506C>T p.P1169L | Missense Mutation (SNP) | VAF 109/353 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- NETO1 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 251/542 reads (46%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NFIB | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 242/405 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NFXL1 | c.1206G>C p.K402N | Missense Mutation (SNP) | VAF 79/243 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- NLRP4 | c.2881G>A p.D961N | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.397); called by muse, varscan2
- NLRP7 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 107/405 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NOL9 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 154/560 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NOTCH3 | c.4532G>A p.G1511D | Missense Mutation (SNP) | VAF 206/593 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- NPFFR2 | c.1179G>A p.W393* | Nonsense Mutation (SNP) | VAF 117/402 reads (29%) | called by muse, mutect2, varscan2
- NPHS1 | c.3644G>A p.G1215E | Missense Mutation (SNP) | VAF 103/382 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- NSFL1C | c.940C>T p.H314Y | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- OR2A14 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 269/884 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- OR4S2 | c.451T>C p.F151L | Missense Mutation (SNP) | VAF 126/427 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- OR51B5 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 95/305 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- OR51S1 | c.716A>C p.E239A | Missense Mutation (SNP) | VAF 126/429 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- OR52J3 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 122/403 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52R1 | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 149/436 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR7C2 | c.549A>T p.E183D | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- PAM | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 125/227 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- PARP14 | c.4596T>A p.S1532R | Missense Mutation (SNP) | VAF 100/372 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- PCDHA7 | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 301/553 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PCDHB1 | c.2060C>T p.S687F | Missense Mutation (SNP) | VAF 237/383 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PCDHB8 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 90/455 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHB8 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 413/1930 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PCK1 | c.945G>A p.M315I | Missense Mutation (SNP) | VAF 95/310 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- PCLO | c.12277G>A p.D4093N | Missense Mutation (SNP) | VAF 120/595 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PEG3 | c.654T>G p.Y218* | Nonsense Mutation (SNP) | VAF 86/281 reads (31%) | called by mutect2, varscan2
- PHF12 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 109/380 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHLDB1 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 145/509 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PIK3C2G | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 92/373 reads (25%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.077); called by muse, mutect2
- PKDREJ | c.4684C>A p.Q1562K | Missense Mutation (SNP) | VAF 129/445 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1L1 | c.1208T>A p.V403D | Missense Mutation (SNP) | VAF 100/390 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.167); called by muse, mutect2
- PLA2G15 | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 113/415 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PLA2G2C | c.137G>T p.C46F | Missense Mutation (SNP) | VAF 83/304 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLA2G2C | c.136T>A p.C46S | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLCB1 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 121/428 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCXD3 | c.806C>T p.T269I | Missense Mutation (SNP) | VAF 169/403 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PLG | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- PLPP7 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 271/480 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLXDC1 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 120/430 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- POMC | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 390/643 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- PPL | c.2812C>T p.L938F | Missense Mutation (SNP) | VAF 146/428 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- PPP4R3C | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAMEF17 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 105/354 reads (30%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PRAMEF19 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 112/379 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRICKLE1 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 132/492 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PRR23A | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 154/558 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.231); called by muse, varscan2
- PTEN | c.469dup p.E157Gfs*23 | Frame Shift Ins (INS) | VAF 66/176 reads (38%) | called by mutect2, pindel, varscan2
- RFPL4A | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RHBDL3 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 150/473 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIMS2 | c.1237G>A p.E413K (on ENST00000666250 / NM_001348490.2; = p.E221K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 120/382 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- RIMS3 | c.229A>T p.K77* | Nonsense Mutation (SNP) | VAF 109/383 reads (28%) | called by mutect2, varscan2
- RNF17 | c.1432G>A p.G478R | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ROBO2 | c.2852G>A p.G951E | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ROBO2 | c.3919G>A p.E1307K | Missense Mutation (SNP) | VAF 92/362 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- RPL3 | c.1091A>C p.D364A | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- RSKR | c.1054C>T p.H352Y | Missense Mutation (SNP) | VAF 90/354 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- SAMD3 | c.1175C>A p.T392K | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- SCN11A | c.4008G>A p.M1336I | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- SDK2 | c.2496G>A p.W832* | Nonsense Mutation (SNP) | VAF 75/293 reads (26%) | called by muse, mutect2, varscan2
- SEMA6B | c.2635G>A p.G879R | Missense Mutation (SNP) | VAF 146/467 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); called by mutect2, varscan2
- SERPINB3 | c.875G>A p.S292N | Missense Mutation (SNP) | VAF 226/535 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- SI | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 82/287 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SIGLEC12 | c.904G>A p.G302R (on ENST00000291707 / NM_053003.4; = p.G184R on NM_033329.2) | Missense Mutation (SNP) | VAF 163/587 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC17A8 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 125/337 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SMARCA5 | c.2321T>C p.F774S | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SNX14 | c.2601T>G p.D867E (on ENST00000314673 / NM_001350535.1; = p.D814E on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SORCS1 | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SOX8 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 166/461 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPAG17 | c.4957G>A p.E1653K | Missense Mutation (SNP) | VAF 83/288 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPAG17 | c.1614C>T p.D538= | Splice Region (SNP) | VAF 71/273 reads (26%) | called by muse, mutect2, varscan2
- SPATS1 | c.476A>C p.H159P | Missense Mutation (SNP) | VAF 155/676 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SPESP1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 133/431 reads (31%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- STAT2 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 107/453 reads (24%) | called by muse, mutect2, varscan2
- STXBP4 | c.1606C>G p.R536G | Missense Mutation (SNP) | VAF 125/358 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SUMF1 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 116/426 reads (27%) | called by muse, mutect2, varscan2
- SYTL2 | c.150T>A p.S50R | Missense Mutation (SNP) | VAF 143/434 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- TACR3 | c.1288A>G p.T430A | Missense Mutation (SNP) | VAF 146/475 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF6L | c.1523G>A p.G508D | Missense Mutation (SNP) | VAF 162/561 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TAFA1 | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 109/377 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCP11L1 | c.1014G>T p.L338F | Missense Mutation (SNP) | VAF 113/349 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- TENM2 | c.1576G>A p.E526K (on ENST00000518659 / NM_001122679.2; = p.E294K on NM_001080428.3) | Missense Mutation (SNP) | VAF 297/439 reads (68%) | SIFT tolerated (0.79); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TENM3 | c.3066G>A p.M1022I | Missense Mutation (SNP) | VAF 118/448 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TET2 | c.5570C>T p.P1857L | Missense Mutation (SNP) | VAF 139/496 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX49 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 91/373 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TGDS | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THRAP3 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 115/358 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TINAG | c.321A>C p.E107D | Missense Mutation (SNP) | VAF 113/467 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TLR3 | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 124/391 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMTC3 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 87/310 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNFSF13B | c.603T>A p.Y201* | Nonsense Mutation (SNP) | VAF 80/261 reads (31%) | called by muse, mutect2, varscan2
- TNRC6B | c.4504C>T p.P1502S (on ENST00000454349 / NM_001162501.2; = p.P1392S on NM_015088.3) | Missense Mutation (SNP) | VAF 138/474 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TPTE | c.1147C>T p.Q383* (on ENST00000618007 / NM_199261.4; = p.Q365* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 26/344 reads (8%) | called by muse, mutect2
- TRAF3 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 95/342 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TRAV12-3 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 114/339 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- TRHDE | c.1304C>T p.T435I | Missense Mutation (SNP) | VAF 89/314 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TRIM22 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 118/409 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TRIM22 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 142/500 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TRIO | c.3079C>T p.L1027F | Missense Mutation (SNP) | VAF 232/480 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRPC3 | c.1805G>C p.W602S (on ENST00000379645 / NM_001366479.2; = p.W529S on NM_003305.2) | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TTF2 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 179/480 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTN | c.51241C>T p.P17081S (on ENST00000591111; = p.P9657S on NM_003319.4) | Missense Mutation (SNP) | VAF 269/509 reads (53%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TUB | c.629C>T p.S210F (on ENST00000299506 / NM_177972.3; = p.S265F on NM_003320.4) | Missense Mutation (SNP) | VAF 132/462 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- TUT4 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 118/454 reads (26%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- TXLNG | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 197/421 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UGT2A1 | c.776_778dup p.Y259dup | In Frame Ins (INS) | VAF 70/266 reads (26%) | called by pindel, varscan2
- UHRF1BP1L | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 101/306 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- USF3 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 126/307 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- USP6 | c.926-1G>A p.X309_splice | Splice Site (SNP) | VAF 62/216 reads (29%) | called by muse, mutect2, varscan2
- VPREB1 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 126/463 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- VSIG10L | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 211/622 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WASHC4 | c.2757T>C p.I919= | Splice Region (SNP) | VAF 80/223 reads (36%) | called by muse, mutect2, varscan2
- ZMYM2 | c.3289G>A p.E1097K | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- ZNF587B | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 153/483 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- ZNF607 | c.1695A>T p.E565D | Missense Mutation (SNP) | VAF 146/483 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF777 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 220/482 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF880 | c.1540C>T p.H514Y | Missense Mutation (SNP) | VAF 131/435 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZYG11A | c.1345C>T p.L449F | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCA13 | c.11226C>T p.Y3742= | Silent (SNP) | VAF 90/380 reads (24%) | called by muse, mutect2, varscan2
- ABCB1 | c.1653C>T p.I551= | Silent (SNP) | VAF 283/626 reads (45%) | called by muse, mutect2, varscan2
- ABCB11 | c.2184G>A p.K728= | Silent (SNP) | VAF 156/283 reads (55%) | called by muse, mutect2, varscan2
- ABCC11 | c.3948C>T p.I1316= | Silent (SNP) | VAF 129/417 reads (31%) | catalogued as COSV62321463; called by muse, mutect2, varscan2
- ACAN | c.5436C>T p.V1812= | Silent (SNP) | VAF 132/442 reads (30%) | called by muse, mutect2, varscan2
- ACSS3 | c.1332C>T p.V444= | Silent (SNP) | VAF 62/267 reads (23%) | catalogued as COSV54093326; called by muse, mutect2, varscan2
- ADGRF5 | c.225C>T p.S75= | Silent (SNP) | VAF 247/496 reads (50%) | called by muse, mutect2, varscan2
- ADGRL3 | c.1986C>T p.A662= (on ENST00000506720 / NM_001322402.2; = p.A594= on NM_015236.6) | Silent (SNP) | VAF 128/491 reads (26%) | catalogued as rs374526766; called by muse, mutect2, varscan2
- AFF1 | c.3261C>T p.V1087= | Silent (SNP) | VAF 94/384 reads (24%) | called by muse, mutect2, varscan2
- AGBL1 | c.3178C>T p.L1060= | Silent (SNP) | VAF 117/373 reads (31%) | called by muse, mutect2, varscan2
- AHCTF1 | c.4089A>G p.E1363= (on ENST00000366508; = p.E1337= on NM_015446.5) | Silent (SNP) | VAF 296/473 reads (63%) | called by muse, mutect2, varscan2
- AMELX | c.210C>T p.S70= | Silent (SNP) | VAF 161/350 reads (46%) | called by muse, mutect2, varscan2
- AP2A1 | c.1632C>T p.T544= | Silent (SNP) | VAF 107/426 reads (25%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.2091C>T p.P697= | Silent (SNP) | VAF 123/338 reads (36%) | catalogued as rs764651264; called by muse, mutect2, varscan2
- ASNS | c.147G>A p.R49= | Silent (SNP) | VAF 160/402 reads (40%) | called by muse, varscan2
- ATP1A3 | c.1329C>A p.I443= (on ENST00000545399 / NM_001256214.2; = p.I430= on NM_152296.5) | Silent (SNP) | VAF 91/290 reads (31%) | called by muse, mutect2, varscan2
- BCL9 | c.1929C>T p.L643= | Silent (SNP) | VAF 257/434 reads (59%) | catalogued as rs143538519; called by muse, mutect2, varscan2
- BDKRB2 | c.999G>A p.V333= | Silent (SNP) | VAF 171/466 reads (37%) | catalogued as rs371075760; called by muse, mutect2, varscan2
- BMP5 | c.813C>T p.L271= | Silent (SNP) | VAF 71/314 reads (23%) | called by muse, mutect2, varscan2
- BOD1L2 | c.123C>T p.I41= | Silent (SNP) | VAF 164/717 reads (23%) | called by muse, mutect2, varscan2
- BTBD11 | c.2493G>A p.R831= (on ENST00000280758 / NM_001018072.2; = p.R368= on NM_001017523.2) | Silent (SNP) | VAF 130/466 reads (28%) | called by muse, mutect2, varscan2
- C16orf72 | c.264C>T p.V88= | Silent (SNP) | VAF 101/361 reads (28%) | catalogued as rs576166338; called by muse, mutect2, varscan2
- C1orf94 | c.645G>A p.E215= (on ENST00000488417 / NM_001134734.2; = p.E25= on NM_032884.5) | Silent (SNP) | VAF 133/428 reads (31%) | catalogued as rs1297884885; called by muse, mutect2, varscan2
- C6 | c.1470C>T p.I490= | Silent (SNP) | VAF 85/335 reads (25%) | catalogued as rs760389028, COSV54705258, COSV54712571; called by muse, mutect2, varscan2
- CA12 | c.987G>A p.R329= | Silent (SNP) | VAF 83/336 reads (25%) | called by muse, mutect2, varscan2
- CACNA2D3 | c.897G>A p.E299= | Silent (SNP) | VAF 69/288 reads (24%) | called by muse, mutect2, varscan2
- CASR | c.2292C>T p.I764= (on ENST00000490131; = p.I841= on NM_000388.4) | Silent (SNP) | VAF 154/471 reads (33%) | called by muse, mutect2, varscan2
- CASZ1 | c.2415G>A p.L805= | Silent (SNP) | VAF 156/515 reads (30%) | catalogued as rs532063463, COSV100681720; called by muse, mutect2, varscan2
- CCN5 | c.111C>T p.P37= | Silent (SNP) | VAF 143/534 reads (27%) | called by muse, mutect2, varscan2
- CD177 | c.351C>T p.L117= | Silent (SNP) | VAF 194/661 reads (29%) | called by muse, mutect2, varscan2
- CD300LB | c.435C>T p.S145= | Silent (SNP) | VAF 115/432 reads (27%) | called by muse, mutect2
- CDH11 | c.33G>A p.L11= | Silent (SNP) | VAF 124/442 reads (28%) | catalogued as COSV51760029; called by muse, mutect2, varscan2
- CDH7 | c.285C>T p.F95= | Silent (SNP) | VAF 127/563 reads (23%) | catalogued as COSV59884426, COSV59896137; called by muse, mutect2, varscan2
- CDX1 | c.717C>T p.S239= | Silent (SNP) | VAF 378/607 reads (62%) | called by muse, mutect2, varscan2
- CELF5 | c.357C>T p.I119= | Silent (SNP) | VAF 119/417 reads (29%) | called by muse, mutect2, varscan2
- CHID1 | c.990C>T p.P330= | Silent (SNP) | VAF 132/404 reads (33%) | called by muse, mutect2, varscan2
- CLEC14A | c.693C>T p.I231= | Silent (SNP) | VAF 147/462 reads (32%) | catalogued as COSV60561668; called by muse, mutect2, varscan2
- CNGA3 | c.276C>T p.D92= | Silent (SNP) | VAF 262/433 reads (61%) | catalogued as COSV99736826; called by muse, mutect2, varscan2
- COL14A1 | c.1815C>T p.S605= | Silent (SNP) | VAF 75/315 reads (24%) | catalogued as rs889956439, COSV52871963; called by muse, varscan2
- COL4A4 | c.2145G>A p.A715= | Silent (SNP) | VAF 198/320 reads (62%) | catalogued as rs773270107, COSV61630100; called by muse, mutect2, varscan2
- COL5A3 | c.666C>T p.P222= | Silent (SNP) | VAF 117/394 reads (30%) | catalogued as rs752395517, COSV99319890; called by muse, mutect2, varscan2
- COL6A3 | c.3411C>T p.I1137= | Silent (SNP) | VAF 297/501 reads (59%) | catalogued as rs368285658, COSV99796899; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSGALNACT1 | c.444C>T p.F148= | Silent (SNP) | VAF 160/521 reads (31%) | catalogued as rs537689859; called by muse, varscan2
- CYP4X1 | c.1314G>A p.Q438= | Silent (SNP) | VAF 95/348 reads (27%) | called by muse, mutect2, varscan2
- DCC | c.2511C>T p.V837= | Silent (SNP) | VAF 95/415 reads (23%) | catalogued as rs575776896, COSV59143655; called by muse, mutect2, varscan2
- DGKH | c.273C>T p.G91= | Silent (SNP) | VAF 69/287 reads (24%) | called by muse, mutect2, varscan2
- DHX37 | c.1083C>T p.F361= | Silent (SNP) | VAF 97/307 reads (32%) | catalogued as rs1435888926; called by muse, mutect2, varscan2
- DMRTB1 | c.333C>T p.P111= | Silent (SNP) | VAF 169/552 reads (31%) | catalogued as rs1222775140; called by muse, mutect2, varscan2
- DNAH14 | c.5043G>A p.R1681= (on ENST00000445597; = p.R2086= on NM_001367479.1) | Silent (SNP) | VAF 106/213 reads (50%) | catalogued as COSV70541522; called by muse, mutect2, varscan2
- DNAH17 | c.10807C>T p.L3603= | Silent (SNP) | VAF 148/439 reads (34%) | called by muse, mutect2, varscan2
- DNAI2 | c.1530G>A p.L510= | Silent (SNP) | VAF 127/370 reads (34%) | catalogued as rs747447796; called by muse, mutect2, varscan2
- DPH6 | c.411T>C p.P137= | Silent (SNP) | VAF 62/160 reads (39%) | called by muse, mutect2, varscan2
- DUXB | c.219G>A p.L73= | Silent (SNP) | VAF 90/315 reads (29%) | called by muse, mutect2, varscan2
- EDN3 | c.243G>A p.Q81= | Silent (SNP) | VAF 165/570 reads (29%) | catalogued as COSV61108774; called by muse, mutect2, varscan2
- EFCAB6 | c.4086G>A p.E1362= | Silent (SNP) | VAF 102/338 reads (30%) | called by muse, mutect2, varscan2
- ELMOD1 | c.492C>T p.F164= | Silent (SNP) | VAF 131/450 reads (29%) | called by muse, mutect2, varscan2
- ENAM | c.1962G>A p.E654= | Silent (SNP) | VAF 91/345 reads (26%) | called by muse, mutect2, varscan2
- EPHA3 | c.2256C>T p.I752= | Silent (SNP) | VAF 94/348 reads (27%) | catalogued as rs1380535477; called by muse, varscan2
- EPPK1 | c.1926C>T p.I642= | Silent (SNP) | VAF 146/479 reads (30%) | catalogued as rs781944296; called by muse, mutect2, varscan2
- ERBB4 | c.2685G>A p.R895= | Silent (SNP) | VAF 177/308 reads (57%) | catalogued as COSV61485327; called by muse, mutect2, varscan2
- EYA4 | c.678C>T p.F226= | Silent (SNP) | VAF 118/283 reads (42%) | catalogued as COSV62060104; called by muse, mutect2, varscan2
- FAAH2 | c.1431C>T p.F477= | Silent (SNP) | VAF 94/243 reads (39%) | catalogued as COSV100887495; called by muse, mutect2, varscan2
- FAM71E2 | c.1563C>T p.S521= | Silent (SNP) | VAF 84/273 reads (31%) | called by muse, mutect2, varscan2
- FAM83B | c.2682C>T p.I894= | Silent (SNP) | VAF 112/492 reads (23%) | called by muse, mutect2, varscan2
- FAT3 | c.609C>T p.L203= | Silent (SNP) | VAF 90/332 reads (27%) | called by muse, mutect2, varscan2
- FBN3 | c.6597G>A p.R2199= | Silent (SNP) | VAF 90/391 reads (23%) | called by muse, mutect2
- FBXL20 | c.333C>T p.T111= | Silent (SNP) | VAF 55/260 reads (21%) | called by muse, mutect2, varscan2
- FGF12 | c.558G>A p.G186= (on ENST00000454309 / NM_021032.5; = p.G124= on NM_004113.6) | Silent (SNP) | VAF 112/396 reads (28%) | catalogued as COSV53154141; called by muse, mutect2, varscan2
- FGF6 | c.612C>T p.F204= | Silent (SNP) | VAF 78/279 reads (28%) | catalogued as COSV57403697; called by muse, mutect2, varscan2
- FJX1 | c.255C>T p.T85= | Silent (SNP) | VAF 197/596 reads (33%) | called by muse, mutect2, varscan2
- FKBP10 | c.615C>T p.V205= | Silent (SNP) | VAF 118/416 reads (28%) | catalogued as rs143446005; ClinVar: likely benign; called by muse, mutect2, varscan2
- FLNA | c.4704C>T p.F1568= | Silent (SNP) | VAF 210/467 reads (45%) | called by muse, mutect2, varscan2
- FLT1 | c.876C>T p.F292= | Silent (SNP) | VAF 120/440 reads (27%) | catalogued as COSV56732088, COSV56733779; called by muse, mutect2, varscan2
- FOXI3 | c.711G>A p.K237= | Silent (SNP) | VAF 294/440 reads (67%) | called by muse, mutect2, varscan2
- FREM1 | c.5886C>T p.F1962= | Silent (SNP) | VAF 209/339 reads (62%) | called by muse, mutect2, varscan2
- FRY | c.7017C>T p.I2339= | Silent (SNP) | VAF 116/347 reads (33%) | called by muse, mutect2, varscan2
- FUT7 | c.489G>A p.S163= | Silent (SNP) | VAF 266/436 reads (61%) | called by muse, varscan2
- GBA3 | c.1344C>T p.V448= | Silent (SNP) | VAF 96/360 reads (27%) | catalogued as COSV72438041, COSV72438235; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.675C>T p.L225= | Silent (SNP) | VAF 55/251 reads (22%) | catalogued as rs560505994; called by muse, mutect2, varscan2
- GFPT2 | c.918C>T p.A306= | Silent (SNP) | VAF 190/345 reads (55%) | called by muse, mutect2, varscan2
- GFRA3 | c.147G>A p.R49= | Silent (SNP) | VAF 294/494 reads (60%) | called by muse, mutect2, varscan2
- GHR | c.1197C>T p.F399= | Silent (SNP) | VAF 258/557 reads (46%) | catalogued as COSV50109103; called by muse, mutect2, varscan2
- GLB1L2 | c.1671C>T p.I557= | Silent (SNP) | VAF 120/393 reads (31%) | catalogued as COSV100335519; called by muse, mutect2, varscan2
- GPD1 | c.714C>T p.F238= | Silent (SNP) | VAF 166/432 reads (38%) | catalogued as rs752964205; called by muse, mutect2, varscan2
- GPR158 | c.1767C>T p.F589= | Silent (SNP) | VAF 81/158 reads (51%) | catalogued as COSV100892912; called by muse, mutect2, varscan2
- GRIA2 | c.1359C>T p.I453= | Silent (SNP) | VAF 140/542 reads (26%) | catalogued as rs752578545, COSV52383835; called by muse, mutect2, varscan2
- GRM3 | c.2046C>T p.F682= | Silent (SNP) | VAF 215/467 reads (46%) | catalogued as COSV64478679, COSV64480448; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1053C>T p.L351= | Silent (SNP) | VAF 259/501 reads (52%) | called by muse, mutect2, varscan2
- GTSE1 | c.946C>T p.L316= | Silent (SNP) | VAF 90/295 reads (31%) | called by muse, mutect2, varscan2
- H1-5 | c.255G>A p.L85= | Silent (SNP) | VAF 125/563 reads (22%) | catalogued as COSV100137902; called by muse, mutect2, varscan2
- HAO2 | c.582C>T p.F194= | Silent (SNP) | VAF 96/299 reads (32%) | called by muse, mutect2, varscan2
- HAS3 | c.951C>T p.D317= | Silent (SNP) | VAF 133/410 reads (32%) | called by muse, mutect2, varscan2
- HBE1 | c.117C>T p.T39= | Silent (SNP) | VAF 74/263 reads (28%) | called by muse, mutect2, varscan2
- HHIP | c.729C>T p.F243= | Silent (SNP) | VAF 129/476 reads (27%) | called by muse, mutect2, varscan2
- HRG | c.339C>T p.S113= | Silent (SNP) | VAF 98/356 reads (28%) | called by muse, mutect2, varscan2
- HYOU1 | c.2337C>T p.S779= | Silent (SNP) | VAF 134/502 reads (27%) | called by muse, mutect2, varscan2
- ICAM1 | c.1002C>T p.A334= | Silent (SNP) | VAF 155/561 reads (28%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.348G>A p.A116= | Silent (SNP) | VAF 56/269 reads (21%) | catalogued as rs555707296; called by muse, mutect2, varscan2
- IL1RL1 | c.1245T>C p.Y415= | Silent (SNP) | VAF 100/353 reads (28%) | called by muse, mutect2, varscan2
- ING1 | c.1038C>T p.L346= | Silent (SNP) | VAF 167/558 reads (30%) | called by muse, mutect2, varscan2
- IQCN | c.627C>T p.P209= | Silent (SNP) | VAF 159/531 reads (30%) | catalogued as rs746966070; called by muse, mutect2, varscan2
- ITIH2 | c.117C>T p.A39= | Silent (SNP) | VAF 60/173 reads (35%) | called by muse, mutect2, varscan2
- ITIH6 | c.2790C>T p.P930= | Silent (SNP) | VAF 207/464 reads (45%) | called by muse, mutect2, varscan2
- KCNK18 | c.30G>A p.R10= | Silent (SNP) | VAF 122/290 reads (42%) | called by muse, mutect2, varscan2
- KIF21B | c.444G>A p.L148= | Silent (SNP) | VAF 164/293 reads (56%) | called by muse, mutect2, varscan2
- KRT1 | c.843G>A p.E281= | Silent (SNP) | VAF 90/326 reads (28%) | catalogued as COSV52869137, COSV99358815, COSV99358859; called by muse, mutect2, varscan2
- KRT34 | c.465C>T p.L155= | Silent (SNP) | VAF 122/409 reads (30%) | catalogued as COSV101222584; called by muse, mutect2, varscan2
- KRTAP29-1 | c.57C>T p.I19= | Silent (SNP) | VAF 193/563 reads (34%) | called by muse, mutect2, varscan2
- LCT | c.1620C>T p.F540= | Silent (SNP) | VAF 324/537 reads (60%) | called by muse, mutect2, varscan2
- LIG3 | c.3009G>A p.R1003= | Silent (SNP) | VAF 95/377 reads (25%) | catalogued as rs747698159; called by muse, mutect2, varscan2
- LRP5 | c.3732C>T p.L1244= | Silent (SNP) | VAF 95/340 reads (28%) | catalogued as rs556919142, COSV53712964; called by muse, mutect2, varscan2
- LRRC14 | c.492C>T p.P164= | Silent (SNP) | VAF 172/534 reads (32%) | catalogued as rs777894589; called by muse, mutect2, varscan2
- LRRC31 | c.804A>G p.Q268= | Silent (SNP) | VAF 53/180 reads (29%) | called by muse, varscan2
- LRRC4C | c.711C>T p.G237= | Silent (SNP) | VAF 143/489 reads (29%) | called by muse, mutect2, varscan2
- LY9 | c.1011C>T p.A337= | Silent (SNP) | VAF 271/438 reads (62%) | called by muse, mutect2, varscan2
- MAST4 | c.7608C>T p.P2536= (on ENST00000403625 / NM_001164664.2; = p.P2347= on NM_015183.3) | Silent (SNP) | VAF 181/760 reads (24%) | catalogued as rs1421442844, COSV55129786; called by muse, mutect2, varscan2
- MECOM | c.1389G>A p.Q463= (on ENST00000468789 / NM_001105078.4; = p.Q651= on NM_004991.4) | Silent (SNP) | VAF 105/391 reads (27%) | called by muse, mutect2, varscan2
- MIEN1 | c.255T>C p.Y85= | Silent (SNP) | VAF 168/460 reads (37%) | called by muse, mutect2, varscan2
- MROH2B | c.2535G>A p.L845= | Silent (SNP) | VAF 235/488 reads (48%) | catalogued as COSV68184481; called by muse, mutect2, varscan2
- MUC16 | c.22545G>A p.G7515= | Silent (SNP) | VAF 95/393 reads (24%) | catalogued as COSV67493093; called by muse, mutect2, varscan2
- MUC2 | c.2694C>T p.T898= | Silent (SNP) | VAF 140/469 reads (30%) | catalogued as rs367972178; called by muse, mutect2, varscan2
- MYH13 | c.114C>T p.C38= | Silent (SNP) | VAF 151/505 reads (30%) | called by muse, mutect2, varscan2
- MYH15 | c.2853G>A p.R951= | Silent (SNP) | VAF 110/410 reads (27%) | catalogued as COSV56319200; called by muse, mutect2, varscan2
- MYL7 | c.63T>C p.G21= | Silent (SNP) | VAF 274/538 reads (51%) | catalogued as rs758373845; called by muse, mutect2, varscan2
- NFAM1 | c.108C>T p.T36= | Silent (SNP) | VAF 132/459 reads (29%) | called by muse, mutect2, varscan2
- NLRP13 | c.690G>A p.T230= | Silent (SNP) | VAF 203/617 reads (33%) | catalogued as rs574504902, COSV61619992; called by muse, mutect2
- NLRP13 | c.156C>T p.F52= | Silent (SNP) | VAF 171/522 reads (33%) | catalogued as COSV61620793; called by muse, mutect2, varscan2
- NLRP7 | c.1359C>T p.I453= | Silent (SNP) | VAF 214/689 reads (31%) | called by muse, mutect2, varscan2
- NLRP8 | c.525G>A p.R175= | Silent (SNP) | VAF 132/430 reads (31%) | catalogued as COSV52583575; called by muse, mutect2, varscan2
- NOX4 | c.1581A>G p.K527= | Silent (SNP) | VAF 70/216 reads (32%) | catalogued as COSV99630198; called by muse, mutect2, varscan2
- NXPH4 | c.651G>A p.G217= | Silent (SNP) | VAF 164/503 reads (33%) | called by muse, varscan2
- NYAP2 | c.1899C>T p.P633= | Silent (SNP) | VAF 261/410 reads (64%) | catalogued as rs878920237; called by muse, mutect2, varscan2
- OPCML | c.654C>T p.I218= | Silent (SNP) | VAF 91/314 reads (29%) | catalogued as COSV59407591; called by muse, mutect2, varscan2
- OR10K1 | c.846C>T p.T282= | Silent (SNP) | VAF 176/312 reads (56%) | called by muse, mutect2, varscan2
- OR11G2 | c.645C>T p.F215= | Silent (SNP) | VAF 92/344 reads (27%) | catalogued as rs766378229; called by muse, mutect2, varscan2
- OR13C2 | c.510G>A p.R170= | Silent (SNP) | VAF 229/386 reads (59%) | catalogued as rs780927989, COSV73377748; called by muse, mutect2, varscan2
- OR2A25 | c.501C>T p.F167= | Silent (SNP) | VAF 216/678 reads (32%) | called by muse, mutect2, varscan2
- OR2M2 | c.531C>T p.F177= | Silent (SNP) | VAF 153/284 reads (54%) | catalogued as COSV62897942; called by muse, mutect2, varscan2
- OR2T1 | c.39C>T p.F13= | Silent (SNP) | VAF 345/588 reads (59%) | called by muse, mutect2, varscan2
- OR4A15 | c.492C>T p.L164= | Silent (SNP) | VAF 116/397 reads (29%) | catalogued as rs759394538; called by muse, mutect2, varscan2
- OR4C15 | c.681C>A p.I227= (on ENST00000314644; = p.I173= on NM_001001920.2) | Silent (SNP) | VAF 130/446 reads (29%) | catalogued as COSV100116199, COSV58951738; called by muse, mutect2, varscan2
- OR4Q2 | c.354G>A p.V118= | Silent (SNP) | VAF 118/331 reads (36%) | called by muse, mutect2, varscan2
- OR52N4 | c.93C>T p.F31= | Silent (SNP) | VAF 150/484 reads (31%) | catalogued as COSV100421779; called by muse, mutect2, varscan2
- OR56B4 | c.513G>A p.Q171= | Silent (SNP) | VAF 106/425 reads (25%) | called by muse, mutect2, varscan2
- OR5BS1P | c.171C>T p.T57= | Silent (SNP) | VAF 125/403 reads (31%) | called by muse, mutect2, varscan2
- OR5D14 | c.690C>T p.I230= | Silent (SNP) | VAF 119/430 reads (28%) | catalogued as COSV100162282, COSV59457621; called by muse, mutect2, varscan2
- OR6C2 | c.933G>A p.K311= | Silent (SNP) | VAF 56/201 reads (28%) | catalogued as rs142594604; called by muse, mutect2, varscan2
- OR6C68 | c.258G>A p.G86= | Silent (SNP) | VAF 86/258 reads (33%) | called by muse, mutect2, varscan2
- OR8B12 | c.216C>T p.F72= | Silent (SNP) | VAF 130/422 reads (31%) | called by muse, mutect2, varscan2
- OR8H1 | c.303C>T p.F101= | Silent (SNP) | VAF 170/564 reads (30%) | called by muse, mutect2, varscan2
- OTOF | c.4071G>A p.E1357= (on ENST00000272371 / NM_194248.3; = p.E590= on NM_004802.4) | Silent (SNP) | VAF 208/341 reads (61%) | catalogued as rs919479076; called by muse, mutect2, varscan2
- OTOGL | c.3996C>T p.F1332= (on ENST00000547103; = p.F1323= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 98/292 reads (34%) | called by muse, mutect2, varscan2
- P2RY10 | c.705C>T p.I235= | Silent (SNP) | VAF 184/379 reads (49%) | called by muse, mutect2, varscan2
- PALD1 | c.778C>T p.L260= | Silent (SNP) | VAF 104/253 reads (41%) | called by muse, mutect2, varscan2
- PALD1 | c.921C>T p.A307= | Silent (SNP) | VAF 189/385 reads (49%) | catalogued as COSV99698209; called by muse, mutect2, varscan2
- PAX7 | c.801C>T p.N267= | Silent (SNP) | VAF 118/377 reads (31%) | called by muse, mutect2, varscan2
- PC | c.1632C>T p.I544= | Silent (SNP) | VAF 140/409 reads (34%) | called by muse, mutect2, varscan2
- PCDH18 | c.2049G>A p.V683= | Silent (SNP) | VAF 117/409 reads (29%) | called by muse, mutect2, varscan2
- PCDHA1 | c.1152G>A p.Q384= | Silent (SNP) | VAF 271/438 reads (62%) | called by muse, mutect2, varscan2
- PCDHA4 | c.945C>T p.S315= | Silent (SNP) | VAF 230/366 reads (63%) | catalogued as rs781898049; called by muse, mutect2, varscan2
- PCDHB13 | c.1140G>A p.G380= | Silent (SNP) | VAF 216/377 reads (57%) | catalogued as COSV53400926; called by muse, mutect2, varscan2
- PCDHB14 | c.354G>A p.R118= | Silent (SNP) | VAF 208/351 reads (59%) | called by muse, mutect2, varscan2
- PCDHB14 | c.501C>T p.L167= | Silent (SNP) | VAF 252/428 reads (59%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1518C>T p.S506= | Silent (SNP) | VAF 412/1922 reads (21%) | catalogued as rs1554281264; called by muse, mutect2, varscan2
- PCDHGA10 | c.882G>A p.L294= | Silent (SNP) | VAF 196/328 reads (60%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.537C>T p.S179= | Silent (SNP) | VAF 291/480 reads (61%) | called by muse, mutect2, varscan2
- PCID2 | c.285C>T p.F95= | Silent (SNP) | VAF 100/331 reads (30%) | called by muse, mutect2, varscan2
- PCK1 | c.516C>T p.I172= | Silent (SNP) | VAF 149/475 reads (31%) | catalogued as rs774522183, COSV60126589; called by muse, mutect2, varscan2
- PI4KA | c.4632G>C p.V1544= | Silent (SNP) | VAF 124/446 reads (28%) | called by muse, mutect2, varscan2
- PLAAT1 | c.378C>T p.I126= (on ENST00000650797; = p.I21= on NM_020386.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 120/445 reads (27%) | catalogued as rs771681103, COSV53233654; called by muse, mutect2, varscan2
- PLCB4 | c.2724G>A p.K908= | Silent (SNP) | VAF 92/297 reads (31%) | catalogued as rs759979500, COSV53808092, COSV53809813; called by muse, mutect2, varscan2
- PLPP3 | c.846G>A p.T282= | Silent (SNP) | VAF 88/274 reads (32%) | catalogued as rs767342556; called by muse, mutect2, varscan2
- PLS1 | c.1791G>A p.R597= | Silent (SNP) | VAF 87/287 reads (30%) | called by muse, mutect2, varscan2
- POGLUT3 | c.768C>T p.P256= | Silent (SNP) | VAF 126/427 reads (30%) | called by muse, mutect2, varscan2
- POLR1B | c.417C>T p.I139= | Silent (SNP) | VAF 295/480 reads (61%) | called by muse, mutect2, varscan2
- POTEA | c.1242G>A p.V414= (on ENST00000519951 / NM_001005365.2; = p.V368= on NM_001002920.1) | Silent (SNP) | VAF 73/304 reads (24%) | catalogued as rs772493687; called by muse, mutect2, varscan2
- PRAMEF12 | c.1077G>A p.G359= | Silent (SNP) | VAF 157/527 reads (30%) | catalogued as rs1279555067, COSV100743555; called by muse, mutect2, varscan2
- PRDM5 | c.252C>T p.F84= | Silent (SNP) | VAF 98/382 reads (26%) | catalogued as rs576918913, COSV53358452; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRDM5 | c.105C>T p.F35= | Silent (SNP) | VAF 75/313 reads (24%) | catalogued as rs867609248, COSV99310487; called by muse, mutect2, varscan2
- PREX2 | c.1149G>A p.E383= | Silent (SNP) | VAF 96/364 reads (26%) | called by muse, mutect2
- PRKDC | c.7353C>T p.L2451= | Silent (SNP) | VAF 117/438 reads (27%) | called by muse, mutect2, varscan2
- PRR4 | c.333C>T p.S111= | Silent (SNP) | VAF 170/763 reads (22%) | catalogued as rs1378193056, COSV57392174; called by muse, mutect2
- PRTN3 | c.336G>A p.A112= | Silent (SNP) | VAF 130/427 reads (30%) | catalogued as rs748605980; called by muse, mutect2, varscan2
- PSG2 | c.831G>A p.G277= | Silent (SNP) | VAF 81/291 reads (28%) | catalogued as COSV61546528; called by muse, mutect2, varscan2
- PTER | c.63C>T p.G21= | Silent (SNP) | VAF 120/258 reads (47%) | called by muse, mutect2, varscan2
- PTPRD | c.4632C>A p.P1544= | Silent (SNP) | VAF 88/301 reads (29%) | called by muse, mutect2, varscan2
- RBM19 | c.1887C>T p.F629= | Silent (SNP) | VAF 121/409 reads (30%) | catalogued as rs1472040456, COSV55694516; called by muse, mutect2, varscan2
- RGS8 | c.36G>A p.G12= (on ENST00000367556 / NM_001369564.2; = p.G30= on NM_033345.3) | Silent (SNP) | VAF 160/252 reads (63%) | called by muse, mutect2, varscan2
- RXFP1 | c.1458G>A p.Q486= | Silent (SNP) | VAF 83/402 reads (21%) | catalogued as rs1272275145; called by muse, mutect2, varscan2
- SAMM50 | c.273C>T p.L91= | Silent (SNP) | VAF 103/330 reads (31%) | catalogued as rs1374188496; called by muse, mutect2, varscan2
- SCN10A | c.1458G>A p.R486= | Silent (SNP) | VAF 90/260 reads (35%) | catalogued as COSV71860712, COSV71862647; called by muse, mutect2, varscan2
- SCN1A | c.1188G>A p.G396= | Silent (SNP) | VAF 152/255 reads (60%) | catalogued as rs267598970, COSV57685406; called by muse, mutect2, varscan2
- SDR42E1 | c.342G>A p.R114= | Silent (SNP) | VAF 163/514 reads (32%) | catalogued as rs1378555720; called by muse, mutect2, varscan2
107 further variants in this file (0 protein-altering or splice-affecting, 71 silent, 36 other) are not listed here.
